Somatic mutation profile of tumor specimen TCGA-B6-A0IN-01A (aliquot TCGA-B6-A0IN-01A-11W-A050-09) from TCGA case TCGA-B6-A0IN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 45.7 years (16,705 days).
Specimen TCGA-B6-A0IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9395f347-d5c2-4f84-ab7d-07838e3b54c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IN-10A (Blood Derived Normal), aliquot TCGA-B6-A0IN-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d9d0177-5954-42ce-9f0a-c6be49a8afdb

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.894A>G p.I298M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs533107085, COSV66859094; called by muse, mutect2, varscan2
- ADAMTS6 | c.893T>A p.I298K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV66859097; called by muse, mutect2, varscan2
- AP1G2 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58112116; called by muse, mutect2
- CDCA7 | c.751G>A p.E251K (on ENST00000347703 / NM_145810.3; = p.E330K on NM_031942.5) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60720296; called by muse, mutect2, varscan2
- DNAH2 | c.6754C>A p.P2252T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV101208957; called by muse, mutect2
- EHBP1 | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99859871; called by muse, mutect2, varscan2
- GRM8 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as rs148553836, COSV100286014; called by muse, mutect2
- MTR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1418638914, COSV63967799; called by muse, mutect2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- OR51A7 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.293); catalogued as COSV63788256; called by mutect2, varscan2
- PARP3 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV67168399; called by muse, mutect2, varscan2
- PCDHB12 | c.2279G>C p.R760T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99506618; called by muse, mutect2
- RARB | c.455G>A p.G152E (on ENST00000383772 / NM_001290216.2; = p.G145E on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58066879; called by muse, mutect2, varscan2
- ROCK1 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 182/441 reads (41%) | catalogued as COSV67695704; called by muse, mutect2, varscan2
- SLC20A2 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as CM131032, COSV60601757; called by muse, mutect2, varscan2
- SLC35F4 | c.707G>A p.R236Q (on ENST00000339762 / NM_001352015.2; = p.R200Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as rs373752532; called by muse, mutect2, varscan2
- SMYD3 | c.531+2T>A p.X177_splice (on ENST00000490107 / NM_001375962.1; = p.X118_splice on NM_022743.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as COSV101193541; called by muse, mutect2
- SNCAIP | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763606466, COSV54408494; called by muse, mutect2, varscan2
- TAF1 | c.3614G>A p.R1205Q (on ENST00000373790 / NM_138923.4; = p.R1226Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/367 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52107545; called by muse, mutect2
- TTN | c.80684C>A p.P26895H (on ENST00000591111; = p.P19471H on NM_003319.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | PolyPhen benign (0.013); catalogued as COSV60010123; called by muse, mutect2, varscan2
- UBE3A | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV99216656; called by muse, mutect2
- EIF2AK3 | c.3241dup p.D1081Gfs*31 | Frame Shift Ins (INS) | VAF 61/290 reads (21%) | called by mutect2, pindel, varscan2
- GATA3 | c.1308dup p.S437Qfs*70 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- IGHM | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.35); called by muse, mutect2, varscan2
- SP3 | c.1566_1569del p.T523Lfs*3 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ATP12A | c.2343C>T p.R781= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV54515280; called by muse, varscan2
- BCO1 | c.102C>T p.R34= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV50729225; called by muse, mutect2, varscan2
- BIN1 | c.1707C>T p.S569= (on ENST00000316724 / NM_001320642.1; = p.S430= on NM_004305.4) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs928950798, COSV52117703; called by muse, mutect2, varscan2
- CCDC136 | c.330G>A p.Q110= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV104400394, COSV52798881; called by muse, mutect2, varscan2
- DMAC2 | c.549T>C p.G183= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1367619346, COSV55728034; called by muse, mutect2, varscan2
- LRRC4B | c.882C>T p.H294= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1167226591, COSV65349545; called by muse, mutect2, varscan2
- RPS9 | c.57C>T p.P19= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs773622158, COSV100256324; called by muse, mutect2
- TIE1 | c.807G>A p.Q269= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV65249391; called by muse, mutect2, varscan2
- ZNF800 | c.66T>C p.Y22= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV56175272; called by muse, mutect2, varscan2
